CCDI case PBCWKJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/bd11931a-ab9c-496e-956f-68b76d54f4b7

Demographics
Sex at birth: female.

Biospecimens (3 samples)
- Sample 0E1HEW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0E1HF8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E1HG7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
